Gene-level copy-number profile of tumor specimen TCGA-A6-3807-01A from TCGA case TCGA-A6-3807, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 53.7 years (19,624 days).
Specimen TCGA-A6-3807-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.ec13a142-1b20-484b-8b5c-c3dfa79966f9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-3807-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7e181910-fce9-4a28-abe8-b439c19a12af

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 405; copy number 2: 14,895; copy number 3: 31,485; copy number 4: 7,618; copy number 5: 1,991; copy number 6: 1,597; copy number 7: 158; copy number 8: 1,386; copy number 9: 69; copy number 10: 37; copy number 11: 169.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-3807-01A-01D-1018-01): tumor purity 0.52, ploidy 3.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–50,124, 1 gene: BNIP3P41.
- chr4:91,108,023–91,112,790, 1 gene: AC004054.1.
- chr8:89,412,621–89,415,071, 1 gene: KRT8P4.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,819 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:74,320,613–74,518,007, 1 gene, copy number 9 (within-gene range 5–9): GDAP1.
- chr8:74,376,687–77,014,028, 32 genes, copy number 9: Y_RNA, MIR5681A, MIR5681B, MIR2052HG, PCBP2P2, AC115837.1, MIR2052, AC011632.1, AC026616.1, PI15, AC011632.2, CRISPLD1, AC100782.1, CASC9, LINC02886, HIGD1AP6, PKMP4, HNF4G, AC011029.1, RNU2-54P, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1, ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18.
- chr8:104,478,539–112,148,825, 77 genes, copy number 7–10 (broad region; genes not listed).
- chr8:112,446,575–112,457,993, 1 gene, copy number 7: AC024996.1.
- chr8:123,041,968–126,292,788, 76 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr12:66,767–4,694,317, 116 genes, copy number 7–11 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 8–11 (broad region; genes not listed).
- chr19:31,520,155–35,313,807, 125 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 405. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
